Surgical pathology report (de-identified scan), TCGA case TCGA-GS-A9TZ, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma), tissue source site Fundacio Clinic per a la Recerca Biomedica, specimen TCGA-GS-A9TZ-01A (Primary Tumor).

CERVICAL LYMPH NODE:

Three tissue fragments, the biggest measures 3,7 x 2,5 x 0,9 cm and the smallest 0,5 x 0,4 x 0,3 cm. The section surface shows a homogeneous whitish color

LEFT CERVICAL LYMPH NODE (EXCISION):

- PRIMARY MEDIASTINAL DIFFUSE LARGE B-CELL LYMPHOMA

Sections show a lymph node with the architecture effaced by atypical lymphoid proliferation, composed by sheets of large and pleomorphic cells, some with Reed-Sternberg morphology, accompanied by a background of small cells.

The neoplastic cells are positive for CD20, CD79a, CD30, CD23, CD22, BCL2, MUM1/IRF4 and BCL6 and negative for CD10, CD15 and EBER. A moderate amount of reactive T-cells, CD3 and CD5 positive is found. Stains for immunoglobulin light chains have not been contributory. The Ki67 proliferative index is 70-80%.

Normal Karyotype

ICD O-3

Lymphoma, diffuse large B cell NOS
Site: Lymph node, cervical
968013
C77.0
J2 8/31/14

Source: NCI Genomic Data Commons file ed4f2d61-a046-4d42-9caa-25ffe7757f4e (TCGA-GS-A9TZ.9A705521-237B-429B-B4F6-5CBF2854E252.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).